Gene-level copy-number profile of tumor specimen 5a84eae1-197e-4463-ad65-59becc from CPTAC case 11LU022, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: GX; Age at diagnosis: 53.0 years (19,370 days).
Specimen 5a84eae1-197e-4463-ad65-59becc: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1e8cf46a-1b64-45c4-b200-41c766916fba.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator a55e011d-f91f-4dbd-98e1-328e05 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/3bd39abd-a912-47ef-a65e-27df8aab9b81

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 533; copy number 1: 1,541; copy number 2: 14,640; copy number 3: 16,557; copy number 4: 9,645; copy number 5: 9,521; copy number 6: 2,210; copy number 7: 2,705; copy number 8: 1,341; copy number 9: 61; copy number 10: 82; copy number 11: 6; copy number 12: 30; copy number 13: 2; copy number 14: 28.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr8:85,714,922–85,794,399, 6 genes: REXO1L12P, REXO1L11P, REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1.
- chr9:9,442,060–9,442,380, 1 gene (within-gene range 0–2): RN7SL5P.
- chr15:34,489,002–34,495,900, 2 genes: HNRNPLP2, FSCN1P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,255 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,646,230–163,076,802, 595 genes, copy number 7–8 (broad region; genes not listed).
- chr1:163,769,339–182,982,318, 382 genes, copy number 7 (broad region; genes not listed).
- chr1:184,051,651–187,686,628, 52 genes, copy number 7 (within-gene range 6–7): TSEN15, Y_RNA, Y_RNA, AL445228.1, RN7SL654P, AL445228.2, C1orf21, AL078645.1, AL078645.2, AL713852.1, EDEM3, NIBAN1, RNU7-13P, LINC01633, RNA5SP72, RNF2, FTH1P25, TRMT1L, SWT1, RPL22P24, RPL5P5, Y_RNA, Y_RNA, AL356273.1, Y_RNA, AL356273.2, AL356273.3, IVNS1ABP, AL078644.1, GS1-279B7.1, RNU7-183P, MCRIP2P2, AL133383.2, LINC01350, Y_RNA, Y_RNA, AL133383.1, HMCN1, AL133553.1, PRG4, TPR, RNU6-1240P, ODR4, PDC-AS1, PDC, AL096803.3, AL096803.1, AL096803.2, PTGS2, PACERR, PLA2G4A, LINC01036.
- chr1:191,823,432–194,198,708, 29 genes, copy number 8 (within-gene range 6–8): LINC02770, AL359081.1, RGS18, AL390957.1, AL513175.1, AL513175.2, RGS21, AL136987.1, RGS1, RGS13, RPS27AP5, MIR4426, AL035407.2, AL035407.1, RGS2, RN7SKP126, ZNF101P2, UCHL5, SCARNA18B, RO60, GLRX2, CDC73, MIR1278, B3GALT2, Metazoa_SRP, LINC01031, AL136456.1, AL357793.1, AL357793.2.
- chr1:194,718,795–238,779,200, 899 genes, copy number 7–8 (broad region; genes not listed).
- chr5:58,198–33,298,066, 485 genes, copy number 8–9 (within-gene range 6–9) (broad region; genes not listed).
- chr5:175,290,731–175,291,252, 1 gene, copy number 9: ARL2BPP6.
- chr6:53,219,261–53,349,179, 5 genes, copy number 7: RNU1-136P, HMGB1P20, ELOVL5, MIR5685, RPS16P5.
- chr6:84,421,028–87,399,749, 52 genes, copy number 7: LINC01611, SMARCE1P2, TBX18, TBX18-AS1, AL590143.1, AL109941.1, AL139806.1, AL122016.1, AL135903.1, KRT18P64, LINC02535, DUTP5, TPT1P6, NT5E, AL589666.2, SNX14, AL589666.1, SYNCRIP, SNHG5, PKMP3, SNORD50B, AL355615.1, SMIM11P1, RNU4-72P, Y_RNA, AL450338.1, AL450338.2, RNU4-12P, RPL7P27, RAB1AP2, NDUFA5P9, AL391417.1, RN7SL643P, AL353133.1, AL353133.2, AL157777.1, AL157777.2, HTR1E, RPL7P29, MTHFD2P2, AL138827.1, RN7SKP209, CGA, RCN1P1, AL139274.2, ZNF292, AL139274.1, GJB7, HSPD1P10, SMIM8, C6orf163, AL096817.1.
- chr7:37,032–25,949,986, 406 genes, copy number 7 (broad region; genes not listed).
- chr8:73,064,543–73,878,854, 17 genes, copy number 8 (within-gene range 6–8): SBSPON, AC100823.1, AC100823.2, C8orf89, PRXL2AP2, RPL7, RDH10, RDH10-AS1, AC111149.1, AC111149.2, STAU2-AS1, STAU2, AC018620.1, AC100784.1, VENTXP6, AC027018.1, AC022826.2.
- chr8:85,833,377–111,757,710, 401 genes, copy number 7–13 (within-gene range 5–13) (broad region; genes not listed).
- chr12:23,529,504–24,562,544, 1 gene, copy number 10 (within-gene range 1–10): SOX5.
- chr12:24,212,421–32,646,050, 181 genes, copy number 7–14 (broad region; genes not listed).
- chr16:25,185,253–25,185,538, 1 gene, copy number 7: RN7SL557P.
- chr20:30,214,765–60,083,872, 719 genes, copy number 7 (broad region; genes not listed).
- chr20:63,895,126–63,936,031, 1 gene, copy number 7 (within-gene range 5–7): DNAJC5.
- chr20:63,919,449–64,327,972, 28 genes, copy number 7: MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1, AL137028.1.

Autosomal genes at a single copy (total copy number 1): 1,538. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
